Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A6EO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A6EO-01A (Primary Tumor).

ICD-O-3

Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Floor y mouth^{NOS} CO 4.9
JW 5/24/13

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge: Surgery and Laryngological Oncology Dept.

Physician in charge:

Clinical diagnosis (suspicion) Cancer of the floor of the mouth infiltrating the mandible T3N1M0

Date of admission:

Material:

1) Material: oral cavity – floor of the mouth. Please examine the marked margins. Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis

Examination performed on:

Squamous cell carcinoma keratinizing G2 of the floor of the mouth.
pT4a, pNO (8070/3 T-51200)*

* codes acc. to ICD-O-3 or SNOMED

Macroscopic description:

Part of the mandible with teeth and floor of the mouth sized: 5,5 x 5 x 5,5 cm. Ulcerated tumour in the the floor of the mouth
1 sized: 3 x 2.8 x 1 cm.

Tumour of the floor of the mouth destroys the bone in the front part of the mandible.

Cancer infiltration also present in the mucosa of the oral vestibule.

Minimum margin of uninvolved tissue is 0.3 cm.

Margins:

2 wire - front 0.2 cm

3 wire - back 0.5 cm

4 wire - base 0.7 cm

5 wire - left side 0.5 cm

6 wire - right side 0.7 cm

Microscopic description:

Carcinoma planoepitheliale keratodes G2 fundi oris.

Cancer infiltrates the skeletal muscles of the floor of the mouth and infiltrates and destroys the mandibular bone. Normal tissue margins as in the macroscopic description.

No proliferation of vessels and nerve stems found.

Assistant:

Pathologist:

Edited

Assistant:

Pathologist:

Edited I

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 8c1e15eb-f9aa-484a-a4f4-e1bd9bcaf20e (TCGA-D6-A6EO.132D99BB-D2A7-4DD1-AD9F-F160BF3E4E1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).